Somatic mutation profile of tumor specimen TCGA-46-3767-01A (aliquot TCGA-46-3767-01A-01D-0983-08) from TCGA case TCGA-46-3767, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 76.4 years (27,912 days).
Specimen TCGA-46-3767-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01296e73-392b-4928-9b63-fd7cadbee136.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-46-3767-10A (Blood Derived Normal), aliquot TCGA-46-3767-10A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/623ae4aa-84f8-4ca1-b978-de1bea61af4a

The open-access MAF lists 130 somatic variants for this specimen: 91 protein-altering or splice-affecting, 37 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 37, Nonsense Mutation 7, Frame Shift Del 3, RNA 2, Splice Site 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 6/23 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC005833.1 | c.1438G>T p.A480S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated, low confidence (0.7); catalogued as rs144271473, COSV52899683; called by mutect2, varscan2
- AC008397.2 | c.1946A>G p.E649G | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.022); catalogued as COSV53208581; called by muse, mutect2, varscan2
- ACVR1B | c.1150G>C p.E384Q | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57778919; called by muse, mutect2, varscan2
- AFDN | c.3349C>T p.R1117C | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs756198307, COSV60037315; called by muse, mutect2, varscan2
- AGAP6 | c.365G>T p.C122F (on ENST00000374056 / NM_001365867.1; = p.C145F on NM_001077665.2) | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV65017658; called by muse, varscan2
- ARHGAP36 | c.785C>A p.S262Y | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52269714, COSV99357717; called by mutect2, varscan2
- ATAD5 | c.1330A>T p.K444* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV58976989; called by muse, mutect2, varscan2
- BIRC6 | c.9076G>T p.G3026W | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV70203407; called by muse, mutect2, varscan2
- C8orf34 | c.412C>A p.R138S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as COSV100446353; called by muse, mutect2, varscan2
- CD163 | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.14); catalogued as COSV63135526; called by muse, mutect2, varscan2
- CD1B | c.937T>A p.L313M | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV63804793; called by muse, mutect2, varscan2
- CDH18 | c.2184C>G p.S728R | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); catalogued as COSV56924162, COSV99935390; called by mutect2, varscan2
- CEP135 | c.1022A>T p.D341V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV57261727; called by muse, mutect2, varscan2
- CHORDC1 | c.994G>C p.D332H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); catalogued as rs1322404188, COSV57706670; called by muse, mutect2, varscan2
- CHRDL1 | c.1024C>G p.P342A (on ENST00000372045; = p.P348A on NM_145234.4) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.991); catalogued as COSV54327158; called by muse, mutect2, varscan2
- CMAS | c.1132G>T p.E378* | Nonsense Mutation (SNP) | VAF 19/147 reads (13%) | catalogued as COSV57557161; called by muse, mutect2, varscan2
- CST8 | c.4C>G p.P2A | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV55671808; called by muse, mutect2, varscan2
- DCDC1 | c.4037G>C p.C1346S (on ENST00000597505 / NM_001367979.1; = p.C453S on NM_020869.3) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57998616, COSV58001381; called by muse, mutect2, varscan2
- DIDO1 | c.1086A>C p.E362D | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.978); catalogued as COSV56629817; called by muse, mutect2, varscan2
- DLK1 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57992718; called by muse, mutect2, varscan2
- DPEP3 | c.1204C>A p.L402M | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV52052173; called by muse, mutect2, varscan2
- DPPA4 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59511821; called by mutect2, varscan2
- DZIP3 | c.2752G>A p.D918N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.986); catalogued as COSV64313062; called by mutect2, varscan2
- EDEM3 | c.631A>G p.I211V | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs142115161, COSV58926506; called by muse, mutect2, varscan2
- EDRF1 | c.992A>G p.Y331C (on ENST00000356792 / NM_001202438.2; = p.Y297C on NM_015608.2) | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61765336; called by muse, mutect2
- ELAVL2 | c.706C>G p.R236G | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.411); catalogued as COSV56366915; called by muse, mutect2, varscan2
- EMILIN2 | c.392C>A p.P131H | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.76); catalogued as COSV99598561; called by mutect2, varscan2
- ENPP3 | c.1339C>T p.R447* | Nonsense Mutation (SNP) | VAF 10/97 reads (10%) | catalogued as rs768656602, COSV62955523; called by mutect2, varscan2
- FABP6 | c.130G>C p.G44R | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as rs1193520497, COSV101221297, COSV67437450; called by muse, mutect2, varscan2
- FBXO43 | c.1108G>T p.D370Y | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV71053654, COSV71054927; called by muse, mutect2, varscan2
- GP2 | c.1126G>T p.V376F (on ENST00000381362 / NM_001007240.3; = p.V373F on NM_001502.4) | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1473344179, COSV56895568; called by muse, mutect2, varscan2
- HEPH | c.380C>G p.P127R (on ENST00000343002; = p.P181R on NM_138737.5) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57968474; called by muse, mutect2, varscan2
- HIF3A | c.1987G>T p.A663S (on ENST00000377670 / NM_152795.4; = p.A594S on NM_022462.4) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as rs779344642, COSV54978000, COSV54980720; called by muse, mutect2, varscan2
- IGSF1 | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63838889; called by muse, mutect2
- IMPG2 | c.1318G>C p.G440R | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.741); catalogued as COSV51982713; called by muse, mutect2, varscan2
- KIDINS220 | c.452A>G p.D151G | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.559); catalogued as COSV99875782; called by mutect2, varscan2
- KRT6B | c.1549T>A p.Y517N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.154); catalogued as COSV52885307; called by mutect2, varscan2
- KRTAP10-7 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.186); catalogued as rs672479, COSV59111750; called by muse, mutect2, varscan2
- LHX9 | c.1144A>T p.S382C | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.619); catalogued as COSV61330386; called by muse, mutect2
- LILRA2 | c.1188C>A p.Y396* | Nonsense Mutation (SNP) | VAF 14/134 reads (10%) | catalogued as COSV52194733; called by muse, mutect2, varscan2
- MAP1LC3C | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs576105560, COSV61803913; called by mutect2, varscan2
- MUC16 | c.12448C>A p.P4150T | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.943); catalogued as COSV67480942; called by mutect2, varscan2
- MYH13 | c.4213G>T p.E1405* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV52836636; called by mutect2, varscan2
- MYH2 | c.1034C>A p.T345N | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV55443961; called by muse, mutect2, varscan2
- MYO1F | c.1488G>A p.W496* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV57798162; called by muse, mutect2, varscan2
- NAA25 | c.2251-2A>T p.X751_splice | Splice Site (SNP) | VAF 10/76 reads (13%) | catalogued as COSV55706869; called by muse, mutect2, varscan2
- NES | c.3226G>T p.D1076Y | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV63962028; called by mutect2, varscan2
- NLRP4 | c.2491T>A p.L831M | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV56719239; called by muse, mutect2, varscan2
- NLRP7 | c.2929G>T p.D977Y (on ENST00000340844 / NM_206828.3; = p.D1006Y on NM_139176.3) | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV60178465; called by muse, mutect2, varscan2
- NT5DC3 | c.1309G>T p.G437C | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV67322343; called by mutect2, varscan2
- NUTM1 | c.2390T>A p.L797Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV59218052; called by muse, mutect2
- OCA2 | c.1093G>T p.A365S | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.732); catalogued as COSV62352715; called by muse, mutect2
- OR10G4 | c.892G>T p.V298L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57978314; called by muse, mutect2, varscan2
- OR2J3 | c.626T>G p.F209C | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV65849443, COSV65849664; called by muse, mutect2
- OR2T1 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.406); catalogued as rs141385938, COSV63542173, COSV63542511; called by muse, mutect2, varscan2
- OR52E6 | c.494T>A p.L165H | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61432769; called by muse, mutect2, varscan2
- OR5T1 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs760019236, COSV57303949; called by muse, mutect2
- PARP12 | c.1679G>T p.R560L | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as COSV99694062; called by muse, mutect2, varscan2
- PCDHAC2 | c.1486C>A p.P496T | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs201156874, COSV53861641; called by muse, mutect2, varscan2
- PDE10A | c.2091G>T p.W697C | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63102324; called by mutect2, varscan2
- PINK1 | c.1225G>C p.G409R | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as CM158495, COSV58632188; called by mutect2, varscan2
- PPP1R15B | c.2039A>G p.E680G | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65816248; called by muse, mutect2, varscan2
- PREX2 | c.2476G>T p.D826Y | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.836); catalogued as COSV55768273, COSV55788475; called by muse, mutect2, varscan2
- PRUNE2 | c.3240C>G p.D1080E | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.057); catalogued as COSV65044692; called by muse, mutect2, varscan2
- PTPRC | c.317C>G p.T106R | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as COSV61417277; called by muse, mutect2
- RNF133 | c.475A>T p.K159* | Nonsense Mutation (SNP) | VAF 15/91 reads (16%) | catalogued as COSV57375891; called by muse, mutect2, varscan2
- RPL17-C18orf32 | c.596A>G p.H199R | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as COSV59088080; called by muse, mutect2, varscan2
- RYR2 | c.4201C>T p.H1401Y | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV63701385; called by muse, mutect2, varscan2
- SERGEF | c.684A>C p.T228= | Splice Region (SNP) | VAF 8/51 reads (16%) | catalogued as COSV56385900; called by muse, mutect2, varscan2
- SIGLEC7 | c.72G>T p.K24N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV58317065, COSV99978946; called by mutect2, varscan2
- SLC18A3 | c.1517G>T p.G506V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1420182993, COSV60329526; called by muse, mutect2, varscan2
- SLC27A5 | c.1585G>T p.V529F | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV54020955; called by mutect2, varscan2
- SLC28A1 | c.278-1G>T p.X93_splice | Splice Site (SNP) | VAF 20/66 reads (30%) | catalogued as COSV54482797; called by muse, mutect2, varscan2
- SNAI1 | c.188C>G p.S63C | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV54864667, COSV99723992; called by muse, mutect2, varscan2
- TAT | c.729del p.I244Sfs*2 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as COSV63533394; called by mutect2, pindel, varscan2
- TEKT3 | c.1410G>C p.Q470H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV58628773; called by muse, mutect2, varscan2
- THADA | c.3602T>A p.I1201K | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.8); PolyPhen benign (0.01); catalogued as COSV57689084; called by muse, mutect2
- TMEM72 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV67460385, COSV67460964; called by muse, mutect2, varscan2
- TNRC6C | c.4595C>T p.T1532I | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56950036; called by muse, mutect2, varscan2
- TPH2 | c.1386T>A p.S462R | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.081); catalogued as rs1406880601, COSV61593269; called by muse, mutect2, varscan2
- TRARG1 | c.305G>C p.R102T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100416739, COSV61563057; called by muse, mutect2, varscan2
- TSPAN3 | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as COSV51215440; called by muse, mutect2
- TTN | c.23447C>A p.T7816K (on ENST00000591111; = p.T6889K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/88 reads (11%) | PolyPhen benign (0.079); catalogued as COSV60219285; called by mutect2, varscan2
- UBE3C | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.054); catalogued as COSV61954866; called by muse, mutect2
- ZC3H12B | c.1388C>A p.P463H | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100161775, COSV59046426; called by muse, mutect2, varscan2
- ZNF442 | c.1615A>C p.T539P | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as COSV54422547; called by mutect2, varscan2
- ZNF835 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV101606357; called by muse, mutect2, varscan2
- GAD2 | c.568_572del p.G190Sfs*12 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel
- IGKV1D-17 | c.97A>T p.M33L | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RAD18 | c.1174del p.E392Kfs*4 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel, varscan2
- ACSM1 | c.687C>T p.T229= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs1451909637, COSV54638355; called by muse, mutect2, varscan2
- AP1AR | c.672A>G p.E224= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV56769942; called by muse, mutect2, varscan2
- CACNA2D1 | c.2898G>T p.T966= (on ENST00000356253 / NM_001366867.1; = p.T954= on NM_000722.4) | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100666714, COSV62382347; called by mutect2, varscan2
- CEL | c.624C>T p.P208= (on ENST00000673714; = p.P205= on NM_001807.6) | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV60828752; called by muse, mutect2, varscan2
- CNTRL | c.1200A>T p.T400= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as COSV53050707; called by muse, mutect2, varscan2
- DDIAS | c.2523T>C p.G841= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV61272793; called by muse, mutect2, varscan2
- FAM111B | c.777A>G p.V259= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs1219337295, COSV59112862; called by muse, mutect2, varscan2
- FAM160A2 | c.600A>T p.P200= | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as COSV56413291; called by muse, mutect2, varscan2
- FCER1A | c.426G>A p.K142= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs1467004457, COSV63667917; called by muse, mutect2, varscan2
- FZD2 | c.963C>T p.G321= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV59529734; called by muse, mutect2, varscan2
- GALNT1 | c.1509C>T p.N503= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as COSV52453923, COSV52454967; called by muse, mutect2
- GRM3 | c.2605C>A p.R869= | Silent (SNP) | VAF 37/140 reads (26%) | catalogued as COSV64466973, COSV64470174; called by muse, mutect2, varscan2
- GUCY1A1 | c.1002G>T p.T334= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV56654518, COSV99638573; called by muse, mutect2, varscan2
- HOXB2 | c.48G>T p.P16= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV57485678, COSV57487779; called by muse, mutect2
- JAKMIP3 | c.2460A>G p.R820= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as COSV53826777; called by muse, mutect2, varscan2
- KIAA0408 | c.2022T>A p.P674= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV100847534; called by muse, mutect2, varscan2
- KIAA1549L | c.1038C>T p.G346= (on ENST00000321505; = p.G643= on NM_012194.3) | Silent (SNP) | VAF 25/153 reads (16%) | catalogued as COSV55778104; called by muse, mutect2, varscan2
- LCE1F | c.90C>A p.P30= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV57669689; called by muse, mutect2, varscan2
- MAP4K1 | c.1684C>T p.L562= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV67711856; called by muse, mutect2, varscan2
- MFN1 | c.177A>T p.G59= | Silent (SNP) | VAF 39/162 reads (24%) | catalogued as rs1238808119, COSV54941352; called by muse, mutect2, varscan2
- MNDA | c.87G>C p.L29= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV63741665, COSV63742300; called by muse, mutect2
- MUC3A | c.7761C>A p.A2587= | Silent (SNP) | VAF 91/640 reads (14%) | catalogued as COSV60221124; called by muse, mutect2, varscan2
- MYO18B | c.7149G>T p.R2383= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV59142374; called by muse, mutect2, varscan2
- NCF2 | c.75C>A p.A25= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as COSV62316280; called by mutect2, varscan2
- PAQR4 | c.639G>A p.A213= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs192812860, COSV51892140; called by mutect2, varscan2
- PKHD1 | c.4146C>A p.L1382= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV61887864; called by muse, mutect2, varscan2
- PLA2G4D | c.300G>A p.E100= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV51822478; called by muse, mutect2, varscan2
- PLXNA4 | c.141C>G p.P47= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV58126862, COSV58146841; called by muse, mutect2, varscan2
- PSG3 | c.108C>A p.V36= | Silent (SNP) | VAF 15/129 reads (12%) | catalogued as COSV59505856; called by muse, mutect2, varscan2
- SEC24A | c.144A>G p.Q48= | Silent (SNP) | VAF 46/321 reads (14%) | catalogued as COSV59747551, COSV59748728; called by muse, mutect2, varscan2
- SERPINB3 | c.27C>T p.T9= | Silent (SNP) | VAF 15/141 reads (11%) | catalogued as COSV52193122; called by muse, mutect2, varscan2
- SLC35D3 | c.1062C>T p.G354= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs771784225, COSV59378103, COSV59378110; called by mutect2, varscan2
- SLCO5A1 | c.810G>C p.A270= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV52664229, COSV52668396; called by muse, mutect2, varscan2
- TENM3 | c.1884G>T p.G628= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV69314560; called by mutect2, varscan2
- TRAV27 | c.207G>T p.T69= | Silent (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- TRIM51 | c.543T>A p.A181= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV55269097; called by muse, mutect2, varscan2
- UFSP2 | c.30C>G p.L10= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV52992382; called by muse, mutect2, varscan2
- MIR493 | n.43G>T | RNA (SNP) | VAF 8/68 reads (12%) | catalogued as rs768709644; called by muse, mutect2
- OR2W5 | n.1261G>T | RNA (SNP) | VAF 9/46 reads (20%) | catalogued as rs760394531; called by mutect2, varscan2
